Somatic mutation profile of tumor specimen TCGA-C5-A1BJ-01A (aliquot TCGA-C5-A1BJ-01A-11D-A13W-08) from TCGA case TCGA-C5-A1BJ, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 34.5 years (12,611 days).
Specimen TCGA-C5-A1BJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 39415f99-5adc-4956-a0bd-b8f6129d4608.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-C5-A1BJ-10A (Blood Derived Normal), aliquot TCGA-C5-A1BJ-10A-01D-A13W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a18ef62a-d8d2-46cb-8b09-0f2d5d03b3ba

The open-access MAF lists 139 somatic variants for this specimen: 111 protein-altering or splice-affecting, 25 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 95, Silent 25, Nonsense Mutation 11, Intron 2, Splice Site 2, Splice Region 1, Translation Start Site 1, RNA 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA12 | c.2098C>T p.P700S (on ENST00000272895 / NM_173076.3; = p.P382S on NM_015657.3) | Missense Mutation (SNP) | VAF 59/262 reads (23%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV55964880, COSV99792553; called by muse, mutect2, varscan2
- ACO1 | c.760C>G p.L254V | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.49); PolyPhen benign (0.043); catalogued as COSV59381224; called by muse, mutect2, varscan2
- ADCY5 | c.1808G>A p.R603H | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.825); catalogued as rs748727996, COSV59200020; called by muse, mutect2, varscan2
- AKAP13 | c.301C>G p.Q101E | Missense Mutation (SNP) | VAF 23/129 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.265); catalogued as COSV63453801; called by muse, mutect2, varscan2
- AKAP6 | c.3842C>G p.S1281C | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs766910356, COSV55219678; called by muse, mutect2, varscan2
- ANAPC1 | c.2110G>A p.D704N | Missense Mutation (SNP) | VAF 7/93 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.436); catalogued as COSV100594493; called by muse, mutect2
- ARHGAP21 | c.1780C>T p.Q594* | Nonsense Mutation (SNP) | VAF 20/87 reads (23%) | catalogued as COSV57607550; called by muse, mutect2, varscan2
- ARHGEF5 | c.394G>C p.E132Q | Missense Mutation (SNP) | VAF 22/208 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.086); catalogued as rs1161937201, COSV50212565; called by muse, mutect2, varscan2
- ASH1L | c.1907C>G p.S636* | Nonsense Mutation (SNP) | VAF 6/144 reads (4%) | catalogued as COSV100853083; called by muse, mutect2
- ATP13A4 | c.13G>C p.E5Q | Missense Mutation (SNP) | VAF 12/175 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.127); catalogued as COSV99793945; called by muse, mutect2
- B4GALT5 | c.1166G>C p.*389Sext*39 | Nonstop Mutation (SNP) | VAF 33/137 reads (24%) | catalogued as COSV65494232; called by muse, mutect2, varscan2
- CAPNS1 | c.289G>C p.E97Q | Missense Mutation (SNP) | VAF 12/360 reads (3%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.95); catalogued as COSV99874431; called by muse, mutect2
- CCDC105 | c.1134C>G p.I378M | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.505); catalogued as COSV52964547; called by muse, mutect2, varscan2
- CCDC88A | c.2545G>C p.D849H | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55064569; called by muse, varscan2
- CCNF | c.373G>C p.E125Q | Missense Mutation (SNP) | VAF 24/308 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.798); catalogued as rs376056912; called by muse, mutect2
- CDCA2 | c.688G>C p.D230H | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.639); catalogued as COSV57946789; called by muse, mutect2, varscan2
- CDK12 | c.425C>T p.S142L | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.721); catalogued as COSV101420341; called by muse, mutect2
- CDK9 | c.342G>C p.L114F | Missense Mutation (SNP) | VAF 8/253 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100953592; called by muse, mutect2
- CEP192 | c.7258G>C p.A2420P | Missense Mutation (SNP) | VAF 58/265 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.274); catalogued as COSV58066651; called by muse, mutect2, varscan2
- CHAF1A | c.1882G>A p.E628K | Missense Mutation (SNP) | VAF 28/160 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV56673446; called by muse, varscan2
- CIBAR2 | c.127C>T p.R43W | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs202030185, COSV73320580; called by muse, mutect2, varscan2
- CLSTN3 | c.1858G>A p.E620K | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.251); catalogued as rs759437086, COSV56937912; called by muse, mutect2, varscan2
- COL11A2 | c.2492C>T p.S831L (on ENST00000341947 / NM_080680.3; = p.S724L on NM_080679.2) | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.394); catalogued as rs121912949, CM000672, CM1510408; called by muse, mutect2, varscan2
- COPG1 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 21/194 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as COSV59115015; called by muse, mutect2, varscan2
- CRACD | c.571C>T p.R191W | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as rs746156043, COSV51724930; called by muse, mutect2, varscan2
- CREBBP | c.674C>T p.P225L | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.097); catalogued as rs776306844, COSV52129337; called by muse, mutect2, varscan2
- CUBN | c.6299G>C p.R2100T | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.683); catalogued as COSV100913236, COSV64719741; called by muse, mutect2, varscan2
- DAO | c.889C>T p.R297C | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as rs764973777, COSV57322547; called by muse, mutect2
- DEPDC4 | c.828C>G p.I276M | Missense Mutation (SNP) | VAF 12/218 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.378); catalogued as COSV100147252, COSV54553521; called by muse, mutect2
- DNAJC4 | c.406C>T p.H136Y | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as COSV54174439; called by muse, mutect2, varscan2
- DZIP1 | c.1033G>C p.D345H | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200658829, COSV61266994; called by muse, mutect2, varscan2
- ECRG4 | c.427G>A p.V143I | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs376920426, COSV53001310; called by muse, mutect2, varscan2
- ELK4 | c.626C>G p.S209* | Nonsense Mutation (SNP) | VAF 14/108 reads (13%) | catalogued as COSV56985268; called by muse, mutect2, varscan2
- EPS15 | c.776C>G p.S259C | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65543411; called by muse, mutect2, varscan2
- GLE1 | c.230C>G p.S77* | Nonsense Mutation (SNP) | VAF 31/204 reads (15%) | catalogued as COSV59408633; called by muse, varscan2
- GPN2 | c.109G>C p.G37R | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.599); catalogued as COSV64652274; called by muse, mutect2
- H2BC4 | c.108G>C p.E36D | Missense Mutation (SNP) | VAF 19/273 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.047); catalogued as COSV100019720; called by muse, mutect2
- HNF4A | c.172G>A p.A58T | Missense Mutation (SNP) | VAF 35/216 reads (16%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs376906221; called by muse, mutect2, varscan2
- HNRNPCL1 | c.715G>A p.E239K | Missense Mutation (SNP) | VAF 19/146 reads (13%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.977); catalogued as COSV58612982; called by muse, mutect2, varscan2
- IRX2 | c.793G>A p.D265N | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.105); catalogued as rs531740600, COSV57412034; called by mutect2, varscan2
- ITGAM | c.521C>G p.S174* | Nonsense Mutation (SNP) | VAF 30/263 reads (11%) | catalogued as COSV54938769, COSV54942214; called by muse, mutect2, varscan2
- KIAA1586 | c.811G>A p.E271K | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.763); catalogued as COSV100875342, COSV66056912; called by muse, mutect2, varscan2
- KIF27 | c.3031G>C p.E1011Q | Missense Mutation (SNP) | VAF 6/140 reads (4%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.796); catalogued as COSV99926591; called by muse, mutect2
- KLHL14 | c.545C>T p.S182L | Missense Mutation (SNP) | VAF 28/136 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.049); catalogued as COSV63833745; called by muse, mutect2, varscan2
- KMT2C | c.11533G>A p.E3845K | Missense Mutation (SNP) | VAF 24/133 reads (18%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.985); catalogued as rs1047176280, COSV100072141, COSV51457984; called by muse, mutect2, varscan2
- KRTAP4-12 | c.34G>C p.D12H | Missense Mutation (SNP) | VAF 19/133 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as COSV67458036; called by muse, mutect2, varscan2
- LRRC15 | c.1340C>T p.T447M | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.431); catalogued as rs768257666, COSV61650568; called by muse, mutect2, varscan2
- MAGI1 | c.4259G>C p.R1420T | Missense Mutation (SNP) | VAF 25/201 reads (12%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.036); catalogued as COSV58333121; called by muse, mutect2, varscan2
- MAP3K4 | c.3091T>C p.Y1031H | Missense Mutation (SNP) | VAF 33/169 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV62335306; called by muse, mutect2, varscan2
- MED1 | c.1555C>T p.Q519* | Nonsense Mutation (SNP) | VAF 32/148 reads (22%) | catalogued as COSV56126263; called by muse, mutect2, varscan2
- MERTK | c.1932C>G p.F644L | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54931650; called by muse, mutect2, varscan2
- MON2 | c.4670C>T p.S1557L | Missense Mutation (SNP) | VAF 5/99 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54809709; called by muse, mutect2
- MST1R | c.1073C>G p.P358R | Missense Mutation (SNP) | VAF 20/346 reads (6%) | SIFT tolerated (0.47); PolyPhen benign (0.012); catalogued as COSV99617595; called by muse, mutect2
- MTA2 | c.43G>A p.E15K | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99603972, COSV99604277; called by muse, mutect2
- MUSK | c.2150C>G p.S717* | Nonsense Mutation (SNP) | VAF 10/168 reads (6%) | catalogued as COSV51885604; called by muse, mutect2
- MYH6 | c.4471G>C p.E1491Q | Missense Mutation (SNP) | VAF 18/277 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100676249, COSV62452554; called by muse, mutect2
- MYH6 | c.1081G>A p.G361R | Missense Mutation (SNP) | VAF 45/218 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs747162281, COSV62452063; called by muse, mutect2, varscan2
- N4BP3 | c.496C>G p.Q166E | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs772816113, COSV51063711; called by muse, mutect2, varscan2
- NCAPG2 | c.2748G>A p.V916= | Splice Region (SNP) | VAF 10/120 reads (8%) | catalogued as COSV99316438; called by muse, mutect2
- OR5L2 | c.621G>C p.E207D | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.069); catalogued as COSV65723292, COSV65724478; called by muse, mutect2, varscan2
- PCP2 | c.346C>G p.Q116E | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.191); catalogued as COSV100222057, COSV60697495; called by muse, mutect2, varscan2
- PGAM1 | c.517C>T p.P173S | Missense Mutation (SNP) | VAF 23/159 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV58355816; called by muse, mutect2, varscan2
- PGBD1 | c.1783G>C p.D595H | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.152); catalogued as COSV52554278; called by muse, mutect2, varscan2
- PHYKPL | c.1120G>C p.D374H | Missense Mutation (SNP) | VAF 29/123 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV57424918; called by muse, mutect2, varscan2
- PKP2 | c.1936G>C p.G646R | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50735051; called by muse, mutect2, varscan2
- PLCG2 | c.455C>G p.S152C | Missense Mutation (SNP) | VAF 25/125 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.688); catalogued as COSV100842737, COSV63871775; called by muse, mutect2, varscan2
- PLEKHH2 | c.298G>A p.D100N | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.136); catalogued as COSV56756728; called by muse, mutect2
- PLPP5 | c.463+1G>A p.X155_splice | Splice Site (SNP) | VAF 22/116 reads (19%) | catalogued as rs1563327250, COSV57671354; called by muse, mutect2, varscan2
- PLXNA1 | c.338A>G p.N113S | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV52528577; called by muse, mutect2, varscan2
- PPTC7 | c.274C>G p.Q92E | Missense Mutation (SNP) | VAF 16/174 reads (9%) | SIFT tolerated (0.85); PolyPhen benign (0.003); catalogued as COSV100845680; called by muse, mutect2
- PRRG2 | c.601C>G p.P201A | Missense Mutation (SNP) | VAF 117/294 reads (40%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.018); catalogued as COSV55869581, COSV55870669; called by muse, varscan2
- RABEP2 | c.1093G>A p.E365K | Missense Mutation (SNP) | VAF 22/298 reads (7%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.968); catalogued as COSV100706794, COSV62868423; called by muse, mutect2
- RAP1GAP | c.1166C>T p.T389M | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV51570952; called by muse, mutect2, varscan2
- REM1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 23/138 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as COSV52427757; called by muse, mutect2, varscan2
- RHOXF1 | c.14T>C p.L5P | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV54295027; called by muse, mutect2, varscan2
- RTN3 | c.1420G>A p.D474N (on ENST00000377819 / NM_001265589.2; = p.D455N on NM_201428.3) | Missense Mutation (SNP) | VAF 10/164 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.153); catalogued as COSV100379836; called by muse, mutect2
- RTN3 | c.2120G>C p.G707A (on ENST00000377819 / NM_001265589.2; = p.G688A on NM_201428.3) | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as COSV100379838; called by muse, mutect2
- RUNX1T1 | c.796C>T p.R266* (on ENST00000265814 / NM_001198628.1; = p.R239* on NM_004349.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 8/51 reads (16%) | catalogued as COSV56147139; called by muse, mutect2, varscan2
- SGSM1 | c.2452G>A p.E818K (on ENST00000400359 / NM_001039948.4; = p.E757K on NM_133454.3) | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.084); catalogued as COSV63082399; called by muse, mutect2, varscan2
- SHCBP1L | c.787C>G p.L263V | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as COSV62355640; called by muse, mutect2, varscan2
- SKAP1 | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61148271; called by muse, mutect2, varscan2
- SLC1A2 | c.1126G>C p.E376Q | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53518350; called by muse, mutect2, varscan2
- SLC4A1AP | c.1223C>G p.S408* | Nonsense Mutation (SNP) | VAF 89/430 reads (21%) | catalogued as COSV58135794; called by muse, mutect2, varscan2
- SLC7A14 | c.1548G>C p.M516I | Missense Mutation (SNP) | VAF 34/315 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as rs115446306; called by muse, mutect2, varscan2
- SMC1B | c.2169G>C p.K723N | Missense Mutation (SNP) | VAF 7/108 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.062); catalogued as COSV62528851; called by muse, mutect2
- SMG1 | c.9551C>A p.S3184Y | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as COSV67172707; called by muse, mutect2, varscan2
- STIL | c.1184C>G p.S395C | Missense Mutation (SNP) | VAF 30/174 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs1553176425, COSV54551410; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SVIL | c.6421C>G p.Q2141E (on ENST00000355867 / NM_021738.3; = p.Q1715E on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/117 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.035); catalogued as COSV100880845; called by muse, mutect2
- TADA2B | c.1055C>G p.S352* | Nonsense Mutation (SNP) | VAF 25/116 reads (22%) | catalogued as COSV53827552; called by muse, mutect2, varscan2
- TENM1 | c.4605G>C p.E1535D | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.88); catalogued as COSV100948945; called by muse, mutect2
- TG | c.6718G>C p.E2240Q | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.11); catalogued as COSV55082630; called by muse, mutect2, varscan2
- TGM6 | c.1679-1G>A p.X560_splice | Splice Site (SNP) | VAF 25/114 reads (22%) | catalogued as rs1216470337, COSV52480003, COSV52481668; called by muse, mutect2, varscan2
- THAP5 | c.559G>A p.D187N (on ENST00000415914 / NM_001130475.3; = p.D145N on NM_182529.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as COSV50811904; called by muse, mutect2, varscan2
- TMEM254 | c.349C>T p.R117W | Missense Mutation (SNP) | VAF 24/175 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.409); catalogued as rs144946848; called by muse, mutect2, varscan2
- TTK | c.2287G>C p.D763H | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.671); catalogued as COSV57884792; called by muse, mutect2, varscan2
- TTN | c.7565T>A p.V2522D (on ENST00000591111; = p.V2476D on NM_003319.4) | Missense Mutation (SNP) | VAF 10/50 reads (20%) | PolyPhen possibly damaging (0.463); catalogued as COSV100601298, COSV60159290; called by muse, mutect2, varscan2
- TUBGCP6 | c.4765G>A p.E1589K | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs755251059, COSV50554977; called by muse, mutect2, varscan2
- TYK2 | c.345G>A p.M115I | Missense Mutation (SNP) | VAF 23/122 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.045); catalogued as COSV53388804; called by muse, mutect2, varscan2
- WDPCP | c.1918C>T p.L640F | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.049); catalogued as COSV55419733, COSV55424263; called by muse, mutect2, varscan2
- XKR6 | c.1912G>C p.E638Q | Missense Mutation (SNP) | VAF 10/178 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100440216; called by muse, mutect2
- ZBTB14 | c.211G>C p.D71H | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100813406; called by muse, mutect2
- ZFP36L1 | c.953C>T p.S318F | Missense Mutation (SNP) | VAF 18/215 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60546129; called by muse, mutect2
- ZMYND10 | c.415G>C p.D139H | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99204476; called by muse, mutect2
- ZNF182 | c.422G>C p.G141A | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV59358028; called by muse, mutect2, varscan2
- ZNF200 | c.610C>T p.R204* | Nonsense Mutation (SNP) | VAF 32/185 reads (17%) | catalogued as rs761950506, COSV67723629; called by muse, mutect2, varscan2
- ZNF415 | c.658G>C p.E220Q | Missense Mutation (SNP) | VAF 9/217 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.195); catalogued as COSV54702654; called by muse, mutect2
- ZNF808 | c.1459G>C p.E487Q | Missense Mutation (SNP) | VAF 27/140 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.896); catalogued as COSV63120443; called by muse, mutect2, varscan2
- ZSCAN21 | c.423G>C p.Q141H | Missense Mutation (SNP) | VAF 10/198 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV99460592; called by muse, mutect2
- ZSCAN21 | c.652G>C p.E218Q | Missense Mutation (SNP) | VAF 12/203 reads (6%) | SIFT tolerated (0.33); PolyPhen benign (0.019); catalogued as rs1388499619, COSV99460600; called by muse, mutect2
- BOP1 | c.811C>T p.R271C | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- TADA2A | c.571G>C p.D191H | Missense Mutation (SNP) | VAF 26/371 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.271); called by muse, mutect2
- ABHD14B | c.627C>T p.L209= | Silent (SNP) | VAF 28/172 reads (16%) | catalogued as COSV59985957; called by muse, mutect2, varscan2
- ADAMTSL3 | c.4005G>A p.K1335= | Silent (SNP) | VAF 10/156 reads (6%) | catalogued as COSV99716728; called by muse, mutect2
- ADCY4 | c.549C>T p.C183= | Silent (SNP) | VAF 3/35 reads (9%) | catalogued as COSV99352915; called by muse, mutect2
- ARFGEF2 | c.1809T>C p.D603= | Silent (SNP) | VAF 13/65 reads (20%) | catalogued as rs142912624; called by muse, mutect2, varscan2
- AURKB | c.582G>A p.K194= | Silent (SNP) | VAF 13/125 reads (10%) | catalogued as COSV60244976, COSV60246127; called by muse, mutect2, varscan2
- BOP1 | c.1080C>T p.I360= | Silent (SNP) | VAF 7/33 reads (21%) | called by muse, mutect2, varscan2
- DBH | c.1853G>A p.*618= | Silent (SNP) | VAF 12/70 reads (17%) | catalogued as COSV67549063, COSV67549519; called by muse, mutect2, varscan2
- DIS3L2 | c.411T>C p.Y137= | Silent (SNP) | VAF 7/51 reads (14%) | catalogued as COSV56057575; called by muse, mutect2, varscan2
- DNAAF5 | c.2013G>A p.A671= | Silent (SNP) | VAF 12/61 reads (20%) | catalogued as rs1231258358, COSV52419160; called by muse, mutect2, varscan2
- GGT1 | c.66C>T p.L22= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV50641603; called by muse, mutect2
- INHBB | c.942C>G p.L314= | Silent (SNP) | VAF 31/133 reads (23%) | catalogued as COSV54678542; called by muse, mutect2, varscan2
- MMP27 | c.1236G>A p.Q412= | Silent (SNP) | VAF 26/264 reads (10%) | catalogued as COSV52781517; called by muse, mutect2
- MYRIP | c.414G>A p.L138= | Silent (SNP) | VAF 4/25 reads (16%) | catalogued as COSV56873058; called by muse, mutect2, varscan2
- NAB1 | c.1335G>C p.L445= | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as COSV100492849; called by muse, mutect2, varscan2
- NLGN2 | c.1164C>G p.L388= | Silent (SNP) | VAF 27/187 reads (14%) | catalogued as rs780868011, COSV57210808; called by muse, mutect2, varscan2
- PCDHA8 | c.183G>A p.P61= | Silent (SNP) | VAF 36/225 reads (16%) | catalogued as COSV65338308; called by muse, varscan2
- PIKFYVE | c.3666C>T p.F1222= | Silent (SNP) | VAF 11/66 reads (17%) | catalogued as COSV100009804, COSV52244013; called by muse, mutect2, varscan2
- RBM18 | c.63G>A p.L21= | Silent (SNP) | VAF 14/161 reads (9%) | catalogued as rs766107835, COSV99938729; called by muse, mutect2
- RHOXF1 | c.15C>A p.L5= | Silent (SNP) | VAF 8/65 reads (12%) | catalogued as COSV54295016; called by muse, mutect2, varscan2
- SCN8A | c.4170G>A p.K1390= | Silent (SNP) | VAF 7/54 reads (13%) | catalogued as COSV61979622, COSV61985254; called by muse, mutect2, varscan2
- SLC18A2 | c.1026C>T p.L342= | Silent (SNP) | VAF 26/308 reads (8%) | catalogued as COSV100041311; called by muse, mutect2
- USP11 | c.1374C>T p.F458= (on ENST00000218348; = p.F415= on NM_001371072.1) | Silent (SNP) | VAF 13/64 reads (20%) | catalogued as COSV54474379; called by muse, mutect2, varscan2
- ZFP36L1 | c.492C>T p.I164= | Silent (SNP) | VAF 9/87 reads (10%) | catalogued as COSV60546137; called by muse, mutect2, varscan2
- ZMAT4 | c.573G>A p.L191= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as rs753809814, COSV52704254; called by muse, mutect2, varscan2
- ZNF79 | c.1212C>T p.L404= | Silent (SNP) | VAF 29/123 reads (24%) | catalogued as COSV61071211; called by muse, mutect2, varscan2
- DLG2 | c.205-65731C>G | Intron (SNP) | VAF 12/163 reads (7%) | called by muse, mutect2
- NCL | c.898+63A>G | Intron (SNP) | VAF 54/283 reads (19%) | catalogued as rs777645386, COSV59546618; called by muse, varscan2
- SNORA71D | n.20C>T | RNA (SNP) | VAF 45/204 reads (22%) | catalogued as rs778326252; called by muse, mutect2, varscan2
